Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A96A, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A96A-01A (Primary Tumor).

[page 1 of 2]
Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

Pathology Report-Summary:

Material:

tumor: 8.5 x 6.5 x 4.0 cm

focal infiltration into capsule, but capsule is intact

Diagnosis:

Type B2/B3-Thymoma

pT1, pNx (0/2), pMx

Masaoka: II

Immunohistochemistry

epithelial cells positive for: CK5/6, some focal cells also positive for CK7
strong membrane staining for EGFR

epithelial cells negative for: CD5, CD117

CD1a and CD99-positive immature T-lymphocytes

CK5/6 ICD-3
Thymoma, Type B2, malignant
path 858413
Thymoma, Type B2/B3
858518
Site: Anterior mediastinum
(B8.1)
JW 4/7/14

Pw TSS dx discrepancy form,
TCGA tumor is Thymoma, Type B2

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____
Completed By (Interviewer Name on _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Type B2/B3 Thymoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Type B2	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	It is a mix of Type B2/B3 Thymoma, major component is B2 this is written in the original path report. In _____ there is no possibility to write mix of B2/B3 in the CQCF. So we decided to put the major component (type B2) in the CQCF.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 44d52754-952f-4691-a460-b8df6427de1f (TCGA-ZB-A96A.BC8B9E80-DB97-4EC1-8588-D9C23DA7B0FB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).